Gene-level copy-number profile of tumor specimen RC-B6SO-TTP1-A from RC case RC-B6SO, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Alive; Primary diagnosis: Anaplastic large cell lymphoma, T cell and Null cell type; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 47.5 years (17,348 days).
Specimen RC-B6SO-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0f629e0d-fb27-4fb0-befc-cd3e57fe72cb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B6SO-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/fce93646-b707-4a77-a53b-380b8d5cc432

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 8,131; copy number 2: 49,470; copy number 3: 776; copy number 4: 13.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:103,367,976–103,389,065, 1 gene (within-gene range 0–1): TAF5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,131. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
